Somatic mutation profile of tumor specimen MP2PRT-PATVTU-TMP1-A (aliquot MP2PRT-PATVTU-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATVTU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,067 days).
Specimen MP2PRT-PATVTU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b607970c-a307-4e20-8e3d-5ac8e7b7dd0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATVTU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATVTU-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48767aaf-dcc9-4aec-8b8f-bf81f7b57d67

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Nonsense Mutation 1, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAND2 | c.911G>T p.C304F (on ENST00000456430 / NM_001162499.2; = p.C211F on NM_012298.3) | Missense Mutation (SNP) | VAF 26/456 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs368642719; called by muse, mutect2
- KRT76 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 32/797 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV60121955; called by muse, mutect2
- MTUS2 | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 45/419 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV70923231; called by muse, mutect2, varscan2
- PDK4 | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50010528; called by muse, mutect2
- LAMA3 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 14/315 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2
- NPR1 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 33/698 reads (5%) | called by muse, mutect2
- FBXO43 | c.1899T>G p.T633= | Silent (SNP) | VAF 103/213 reads (48%) | called by muse, mutect2, varscan2
- AP003393.1 | n.921G>A | RNA (SNP) | VAF 193/444 reads (43%) | catalogued as rs748044781; called by muse, mutect2, varscan2
